Gene-level copy-number profile of tumor specimen ALCH-AEG5-TTP1-A from ALCHEMIST case ALCH-AEG5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,341 days).
Specimen ALCH-AEG5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d4c04bc9-da49-4511-b19d-45fc63602c51.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEG5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/277e0a12-411a-4833-95fa-6f6ed819afda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,013; copy number 2: 52,795; copy number 3: 4,533; copy number 4: 10; copy number 5: 33; copy number 6: 1; copy number 7: 1; copy number 10: 6.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:673,580–689,271, 2 genes (within-gene range 0–2): MYL5, SLC49A3.
- chr14:102,539,644–102,555,826, 2 genes: MIR4309, LINC02323.
- chr15:41,828,095–41,848,155, 2 genes (within-gene range 0–2): JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr17:82,078,338–82,098,294, 1 gene: FASN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:995,966–998,051, 1 gene, copy number 5: AL645608.7.
- chr15:21,298,233–21,981,245, 39 genes, copy number 5–10: AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr17:81,239,305–81,241,310, 1 gene, copy number 6: NDUFAF8.

Autosomal genes at a single copy (total copy number 1): 737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
